CCDI case PBCKIZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9c75e283-8c9e-4feb-8f4c-fbf23ea49ed2

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Cerebrum; Age at diagnosis: 2.2 years (817 days).

Biospecimens (3 samples)
- Sample 0DU08Z: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVBR9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVBRM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
